Somatic mutation profile of tumor specimen 0DELKO from CCDI case PBBPVS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.2 years (6,292 days).
Specimen 0DELKO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8e6f61d-46ec-4784-aa5b-4e950b25746c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DELJ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6be76fec-9fed-4d98-9f87-00df022afd66

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.1491C>A p.N497K | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); catalogued as rs1364476987, CM166877; called by muse, varscan2
- MYOCD | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs753297107, COSV100590708, COSV58504368; called by muse, mutect2
- RNF113A | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 187/487 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65097752; called by muse, mutect2, varscan2
- DCDC2 | c.801C>A p.D267E | Missense Mutation (SNP) | VAF 128/289 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- HERC4 | c.1442A>C p.Q481P | Missense Mutation (SNP) | VAF 142/287 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- HIC2 | c.890A>T p.E297V | Missense Mutation (SNP) | VAF 50/596 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2
- KHDC1L | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PHF6 | c.562G>C p.D188H (on ENST00000332070 / NM_032458.3; = p.D189H on NM_032335.3) | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SLC30A3 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 97/526 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLITRK4 | c.675A>C p.K225N | Missense Mutation (SNP) | VAF 181/401 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANO1 | c.2619G>A p.S873= | Silent (SNP) | VAF 297/625 reads (48%) | catalogued as rs1021543138, COSV100797399; called by muse, mutect2, varscan2
- SLC6A1 | c.660C>T p.I220= | Silent (SNP) | VAF 54/806 reads (7%) | catalogued as rs760984163; called by muse, mutect2
- TMEM71 | c.615G>A p.L205= (on ENST00000523829 / NM_001382398.1; = p.L186= on NM_144649.3) | Silent (SNP) | VAF 249/538 reads (46%) | called by muse, mutect2, varscan2
- ZCCHC8 | c.1695C>A p.L565= | Silent (SNP) | VAF 115/669 reads (17%) | catalogued as COSV100288850; called by muse, mutect2, varscan2
- ZFHX4 | c.6009G>A p.P2003= | Silent (SNP) | VAF 198/491 reads (40%) | catalogued as rs372114316; called by muse, mutect2, varscan2
